Somatic mutation profile of tumor specimen 0DPCXU from CCDI case PBCAKM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 17.3 years (6,303 days).
Specimen 0DPCXU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6a8e723-484c-44e3-b1e5-f68609f0d247.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPCXN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09ee4ab1-510a-4fe8-9e6d-9154dc729959

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 3, Missense Mutation 2, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5126A>G p.D1709G | Missense Mutation (SNP) | VAF 216/523 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1555366979, COSV58615493, COSV58625198; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DICER1 | c.1049_1051delinsA p.T350Nfs*10 | Frame Shift Del (DEL) | VAF 316/814 reads (39%) | called by pindel, varscan2*
- PSMD1 | c.2660C>G p.A887G | Missense Mutation (SNP) | VAF 32/858 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.222); called by muse, mutect2
- CCDC151 | c.*49_*68del | 3'UTR (DEL) | VAF 92/215 reads (43%) | called by mutect2, pindel, varscan2
- TAP2 | c.*78T>C | 3'UTR (SNP) | VAF 206/315 reads (65%) | called by muse, mutect2, varscan2
- TBL3 | c.*1028_*1032delinsT | 3'UTR (DEL) | VAF 28/79 reads (35%) | called by pindel, varscan2*
- WARS1 | c.-343del | 5'UTR (DEL) | VAF 154/434 reads (35%) | called by mutect2, pindel, varscan2
